Somatic mutation profile of tumor specimen C3N-01194-04 (aliquot CPT0079050009) from CPTAC case C3N-01194, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 69.8 years (25,483 days).
Specimen C3N-01194-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aae753d-c94d-412b-973b-0b41d1f50cd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01194-31 (Blood Derived Normal), aliquot CPT0079090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c538b22c-efb1-4f71-b34f-938ccaaadcb5

The open-access MAF lists 339 somatic variants for this specimen: 227 protein-altering or splice-affecting, 70 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 70, Nonsense Mutation 18, Intron 18, RNA 7, 5'UTR 7, Splice Region 6, 3'UTR 6, Frame Shift Del 5, Splice Site 3, 5'Flank 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 82/607 reads (14%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL6B | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV50513868; called by muse, mutect2, varscan2
- AGRN | c.2148G>A p.P716= | Splice Region (SNP) | VAF 110/572 reads (19%) | catalogued as rs773715463; called by muse, mutect2, varscan2
- AMOTL2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs761943709; called by muse, mutect2, varscan2
- ANKRD7 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54555312; called by muse, mutect2, varscan2
- ARAP2 | c.4478G>T p.G1493V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317288028; called by muse, mutect2, varscan2
- BMP3 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as rs772205872; called by muse, mutect2, varscan2
- CCDC88A | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV55072294; called by muse, mutect2, varscan2
- CKAP5 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 25/210 reads (12%) | catalogued as COSV100371375; called by muse, mutect2, varscan2
- COL12A1 | c.9148G>A p.A3050T | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as rs1408621028; called by muse, mutect2
- COL6A1 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 114/701 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141572895; called by muse, mutect2, varscan2
- CSMD3 | c.10430C>A p.P3477H (on ENST00000297405 / NM_001363185.1; = p.P3308H on NM_052900.3) | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52133312; called by muse, mutect2, varscan2
- CSNK2A3 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV57145092; called by muse, mutect2, varscan2
- CUBN | c.10633G>T p.A3545S | Missense Mutation (SNP) | VAF 60/632 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV100912271; called by muse, mutect2
- CYBB | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101059781; called by muse, mutect2, varscan2
- DCAF4L2 | c.587C>A p.A196E | Missense Mutation (SNP) | VAF 65/581 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.868); catalogued as COSV60476507; called by muse, mutect2, varscan2
- DDX54 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58376477; called by muse, mutect2, varscan2
- DIDO1 | c.4865G>A p.G1622D | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1193691238; called by muse, mutect2, varscan2
- EHBP1L1 | c.3911G>T p.G1304V | Missense Mutation (SNP) | VAF 78/481 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs569436317; called by muse, mutect2, varscan2
- EP300 | c.7018G>A p.V2340I | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs558456063; ClinVar: not provided; called by muse, mutect2, varscan2
- EPHA4 | c.2437G>A p.V813I | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs775509386; called by muse, mutect2, varscan2
- EPHA8 | c.1069C>A p.R357S | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs1248963963; called by muse, mutect2, varscan2
- ERC2 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 56/500 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55617332; called by muse, mutect2, varscan2
- FZD10 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1421592086; called by muse, mutect2, varscan2
- GJA10 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 22/363 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV101005301; called by muse, mutect2
- GOLGA6L2 | c.1836C>A p.D612E | Missense Mutation (SNP) | VAF 50/739 reads (7%) | SIFT tolerated, low confidence (0.89); catalogued as COSV61486012; called by muse, mutect2
- GPR158 | c.2110T>A p.W704R | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767061963; called by muse, mutect2
- GRIN2A | c.1900T>A p.W634R | Missense Mutation (SNP) | VAF 52/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58047604; called by muse, mutect2, varscan2
- HDAC4 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 70/517 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs748009148; called by muse, varscan2
- HERC2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs775829993; called by muse, mutect2
- HYDIN | c.8077G>A p.E2693K | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs374866149, COSV59271323; called by muse, mutect2, varscan2
- ITGA10 | c.2515A>G p.N839D | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1553745685; called by muse, mutect2
- ITIH3 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 53/571 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.021); catalogued as rs1475328176, COSV69650482; called by muse, mutect2
- KDM5C | c.2827C>G p.R943G | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.176); catalogued as COSV64768471; called by muse, mutect2, varscan2
- KRT12 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 141/749 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99288996; called by muse, mutect2, varscan2
- LATS2 | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.097); catalogued as COSV66875624; called by muse, mutect2
- LENG8 | c.1346A>T p.E449V | Missense Mutation (SNP) | VAF 47/351 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs780323687; called by muse, mutect2, varscan2
- LINGO2 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58056542; called by muse, mutect2, varscan2
- LONRF2 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 24/268 reads (9%) | catalogued as rs755707298; called by muse, mutect2
- LRP1B | c.10928C>A p.A3643D | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.812); catalogued as COSV67193348, COSV67287442; called by muse, mutect2, varscan2
- LRP1B | c.6179G>C p.R2060P | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs748605226, COSV67283743, COSV67287558; called by muse, mutect2
- MUC17 | c.12082C>G p.L4028V | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV60306461; called by muse, mutect2
- MUC2 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.31); catalogued as rs750954497; called by muse, mutect2, varscan2
- OR2T35 | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as rs1420943395, COSV100442422; called by muse, mutect2, varscan2
- OR5K3 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.066); catalogued as rs540804625; called by muse, mutect2, varscan2
- OR5M10 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 65/535 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99074298; called by muse, mutect2, varscan2
- OR6T1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV100189819; called by muse, mutect2
- OR9Q2 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV61112340; called by muse, mutect2, varscan2
- PAGE5 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV99215696; called by mutect2, varscan2
- PCDHB2 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV50609602; called by muse, mutect2, varscan2
- PCDHB2 | c.1335C>A p.D445E | Missense Mutation (SNP) | VAF 89/898 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782393794; called by muse, mutect2, varscan2
- PCDHGA11 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53932061, COSV54018738; called by muse, mutect2, varscan2
- PDE1C | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58510416; called by muse, mutect2
- PPP2R3A | c.2487C>A p.H829Q | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53864021; called by muse, mutect2
- RASSF5 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs782799384, COSV62427642; called by muse, mutect2, varscan2
- RFC3 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs769916582; called by muse, mutect2, varscan2
- RFX6 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.307); catalogued as COSV100263944, COSV60588058; called by muse, mutect2
- RPA1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1360031402; called by muse, mutect2, varscan2
- SCIN | c.846C>A p.C282* (on ENST00000297029 / NM_001112706.3; = p.C35* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 31/292 reads (11%) | catalogued as rs1316915407, COSV51691891; called by muse, mutect2, varscan2
- SEL1L2 | c.1928G>T p.R643L | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs531215174, COSV53149001, COSV99533699; called by muse, mutect2, varscan2
- SLC25A19 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 108/714 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763480652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC34A1 | c.1862C>A p.P621H | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV53690233; called by muse, mutect2, varscan2
- SLCO1B1 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.125); catalogued as COSV99918303; called by muse, mutect2, varscan2
- SOX6 | c.2086C>G p.R696G (on ENST00000528429 / NM_001145819.2; = p.R669G on NM_017508.3) | Missense Mutation (SNP) | VAF 81/829 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57056760; called by muse, mutect2, varscan2
- SOX8 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99559411; called by muse, mutect2, varscan2
- SPAM1 | c.259G>C p.G87R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.709); catalogued as COSV56142410; called by muse, mutect2, varscan2
- STXBP1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 66/521 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV64813822; called by muse, mutect2, varscan2
- TAS1R2 | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 83/565 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.695); catalogued as COSV64746622; called by muse, mutect2, varscan2
- TESC | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58813111; called by muse, mutect2
- TLL1 | c.1721-1G>T p.X574_splice | Splice Site (SNP) | VAF 22/299 reads (7%) | catalogued as COSV50306681, COSV99289298; called by muse, mutect2
- TMEM120B | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs770014935, COSV61186023; called by muse, mutect2, varscan2
- TP53 | c.102del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 50/368 reads (14%) | catalogued as COSV52833841; called by mutect2, pindel, varscan2
- TRMT12 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV60777878; called by muse, mutect2, varscan2
- TTC4 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs762345490; called by muse, mutect2, varscan2
- TTN | c.82744C>G p.H27582D (on ENST00000591111; = p.H20158D on NM_003319.4) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | PolyPhen probably damaging (0.996); catalogued as COSV60105714; called by muse, mutect2
- TTN | c.68672C>A p.T22891N (on ENST00000591111; = p.T15467N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/185 reads (11%) | PolyPhen possibly damaging (0.732); catalogued as COSV60330253; called by muse, mutect2, varscan2
- UPK1B | c.75C>A p.C25* | Nonsense Mutation (SNP) | VAF 32/324 reads (10%) | catalogued as COSV51767031; called by muse, mutect2
- ZFP91 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); catalogued as COSV60162282; called by muse, mutect2
- ZGPAT | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs961903105; called by muse, mutect2, varscan2
- ABCA5 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ADCY7 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRV1 | c.13900G>T p.E4634* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- AGBL1 | c.1251C>A p.C417* | Nonsense Mutation (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- AHNAK2 | c.13801C>A p.P4601T | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); called by muse, mutect2
- AIRE | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AL592490.1 | c.82A>G p.M28V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ANKRD13B | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, varscan2
- ANO6 | c.1678G>T p.V560F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- APBB1IP | c.1213A>G p.R405G | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ARNT | c.532A>T p.I178F | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ARNTL | c.1472_1478del p.G491Efs*3 (on ENST00000403290 / NM_001297719.2; = p.G490Efs*3 on NM_001178.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/196 reads (9%) | called by mutect2, pindel
- BNIP5 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- BPIFB2 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf90 | c.157C>A p.P53T (on ENST00000399645 / NM_001353385.2; = p.P44T on NM_001080524.2) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.035); called by muse, mutect2
- C21orf91 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, varscan2
- C6orf163 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- CACNA1C | c.2158G>T p.G720C | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPZA3 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CBLIF | c.840C>A p.Y280* | Nonsense Mutation (SNP) | VAF 59/344 reads (17%) | called by muse, mutect2, varscan2
- CDK2 | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CIZ1 | c.2531T>G p.V844G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- COL5A1 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPED1 | c.2780A>T p.H927L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREM | c.716C>A p.A239D (on ENST00000429130; = p.A15D on NM_182717.2) | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRTC2 | c.606G>T p.G202= | Splice Region (SNP) | VAF 12/84 reads (14%) | called by muse, varscan2
- DOCK1 | c.2272C>A p.Q758K | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DOK7 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPP10 | c.1496del p.P499Qfs*23 | Frame Shift Del (DEL) | VAF 23/196 reads (12%) | called by mutect2, pindel, varscan2
- DST | c.5941C>A p.Q1981K | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- EEF2K | c.1234T>A p.W412R | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- EIF3D | c.1076G>C p.R359P | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELMO2 | c.1052T>C p.M351T | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EMILIN2 | c.2695+1_2695+2dup | Frame Shift Ins (INS) | VAF 30/346 reads (9%) | called by mutect2, pindel
- ETS1 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.201); called by muse, mutect2
- FAH | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 91/836 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT3 | c.11223G>C p.K3741N | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2
- FUBP3 | c.192A>G p.V64= | Splice Region (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- GJA8 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 67/407 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- GON4L | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 69/598 reads (12%) | called by muse, mutect2, varscan2
- GPD2 | c.2099G>T p.R700L | Missense Mutation (SNP) | VAF 69/613 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GPR142 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- GRAMD1B | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); called by muse, mutect2
- GREB1L | c.2166G>T p.Q722H | Missense Mutation (SNP) | VAF 66/561 reads (12%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.814); called by mutect2, varscan2
- GRIN3B | c.2699C>G p.P900R | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC4 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 58/456 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, varscan2
- HIVEP2 | c.3558G>T p.Q1186H | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HNRNPA3 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IAPP | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGHM | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- INSL5 | c.79A>T p.R27* | Nonsense Mutation (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- INTS8 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- IPO8 | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ITCH | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- ITGB2 | c.1877A>T p.E626V (on ENST00000302347; = p.E602V on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/577 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGB4 | c.5168G>T p.G1723V | Missense Mutation (SNP) | VAF 108/1024 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNQ5 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- KMT2A | c.6149+5G>T | Splice Region (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- KRI1 | c.1880A>T p.E627V | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LAMA1 | c.4595T>C p.L1532P | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA2 | c.1591T>A p.Y531N | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LRIG3 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- LRP2 | c.8209G>T p.A2737S | Missense Mutation (SNP) | VAF 67/617 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCL1 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2
- MEGF8 | c.2807G>T p.G936V (on ENST00000251268 / NM_001271938.2; = p.G869V on NM_001410.3) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFSD2A | c.795C>G p.I265M (on ENST00000372809 / NM_001136493.3; = p.I252M on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- MMP10 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- MSH2 | c.31T>G p.L11V | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- MYLK | c.2498G>A p.G833D | Missense Mutation (SNP) | VAF 73/910 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.147); called by muse, mutect2
- MYO10 | c.3346C>T p.Q1116* | Nonsense Mutation (SNP) | VAF 84/349 reads (24%) | called by muse, mutect2, varscan2
- MYO1E | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 66/559 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYT1 | c.2080G>T p.G694C | Missense Mutation (SNP) | VAF 19/293 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- NIPBL | c.2615A>G p.H872R | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOM1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- NOS1 | c.2649G>A p.R883= | Splice Region (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- NRXN3 | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2
- NWD2 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- OLIG1 | c.721G>C p.G241R | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- OPRL1 | c.455T>A p.I152N | Missense Mutation (SNP) | VAF 91/629 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OR2AG1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- OR4X2 | c.724T>C p.F242L | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51E2 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 43/403 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR51T1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- OR56A5 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR6V1 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- P4HA1 | c.1369A>C p.M457L | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- PAG1 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PAK5 | c.1739G>T p.G580V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PANX2 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- PARP4 | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCIF1 | c.1812C>G p.F604L | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- PDE8A | c.2378G>C p.W793S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PHC2 | c.2027G>T p.R676L (on ENST00000257118 / NM_198040.2; = p.R141L on NM_004427.4) | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLB1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by muse, mutect2
- PLB1 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.646); called by muse, mutect2
- PLET1 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 46/620 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2
- PLXNC1 | c.2069C>G p.A690G | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PMFBP1 | c.2798T>C p.V933A (on ENST00000537465; = p.V928A on NM_031293.3) | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- POLD3 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- PPP1R9B | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- PUM1 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- R3HDM1 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- RASSF8 | c.1193C>G p.P398R | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2
- RELN | c.2966C>A p.T989K | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.058); called by muse, mutect2
- RFX6 | c.2350G>T p.G784* | Nonsense Mutation (SNP) | VAF 21/456 reads (5%) | called by muse, mutect2
- RNF103 | c.1966C>T p.R656* | Nonsense Mutation (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- RP1L1 | c.2925G>T p.L975F | Missense Mutation (SNP) | VAF 142/783 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RPS4Y1 | c.262+2T>A p.X88_splice | Splice Site (SNP) | VAF 50/143 reads (35%) | called by muse, mutect2, varscan2
- RTTN | c.5866C>T p.L1956F | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.181); called by muse, mutect2
- SALL3 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SCN1A | c.5274C>A p.N1758K (on ENST00000303395 / NM_001202435.3; = p.N1747K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/464 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); called by muse, mutect2
- SCN7A | c.2671G>C p.G891R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- SETD5 | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 138/508 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.115); called by muse, varscan2
- SH3KBP1 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SHB | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- SIPA1L3 | c.5000C>G p.S1667* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2
- SLC1A3 | c.326del p.A109Gfs*3 | Frame Shift Del (DEL) | VAF 101/606 reads (17%) | called by mutect2, pindel, varscan2
- SLC38A10 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SLCO1C1 | c.676+1G>T p.X226_splice | Splice Site (SNP) | VAF 16/130 reads (12%) | called by muse, varscan2
- SLIT3 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SPTB | c.701T>A p.L234Q | Missense Mutation (SNP) | VAF 51/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- STON2 | c.1376C>T p.P459L (on ENST00000649389 / NM_001366849.2; = p.P402L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- STRA8 | c.622G>T p.A208S (on ENST00000275764; = p.A186S on NM_182489.2) | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SUGP2 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 75/580 reads (13%) | called by muse, mutect2, varscan2
- TAAR5 | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.886); called by mutect2, varscan2
- TAF4B | c.1779del p.A594Hfs*9 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- TARS3 | c.1846G>A p.G616R | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TENM1 | c.8023G>C p.A2675P | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TG | c.7823T>C p.V2608A | Missense Mutation (SNP) | VAF 99/819 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- TH | c.582C>A p.V194= (on ENST00000381178 / NM_199292.3; = p.V163= on NM_000360.4) | Splice Region (SNP) | VAF 89/730 reads (12%) | called by muse, mutect2, varscan2
- TJP1 | c.3739C>G p.P1247A | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.156); called by muse, mutect2
- TLR7 | c.1244G>T p.S415I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TMC5 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TMEM117 | c.1516A>T p.T506S | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- TOPAZ1 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TTL | c.929A>T p.Q310L | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TVP23A | c.176T>C p.F59S | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- UBE2Z | c.569G>C p.S190T | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, varscan2
- VN1R4 | c.304A>T p.S102C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR53 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 24/295 reads (8%) | called by muse, mutect2
- WNK1 | c.4285C>T p.P1429S (on ENST00000315939 / NM_018979.4; = p.P1182S on NM_014823.3) | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFP62 | c.2554A>G p.R852G (on ENST00000502412 / NM_001377944.1; = p.R819G on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.419); called by muse, mutect2
- ZNF107 | c.2098G>C p.A700P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF45 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ZNF471 | c.1598A>C p.H533P | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF479 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF717 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ABCA1 | c.6585C>T p.S2195= | Silent (SNP) | VAF 21/290 reads (7%) | called by muse, mutect2
- ACBD4 | c.690C>T p.C230= (on ENST00000376955 / NM_001378111.1; = p.L234= on NM_024722.4) | Silent (SNP) | VAF 64/492 reads (13%) | called by muse, mutect2, varscan2
- ADAD2 | c.1359A>T p.P453= (on ENST00000315906 / NM_001145400.2; = p.P535= on NM_139174.4) | Silent (SNP) | VAF 15/280 reads (5%) | called by muse, mutect2
- ADAMTS8 | c.315C>A p.T105= | Silent (SNP) | VAF 31/277 reads (11%) | catalogued as rs749630101; called by muse, mutect2, varscan2
- APBB1IP | c.1143C>T p.C381= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ARHGAP36 | c.1086T>C p.I362= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- BRINP1 | c.1005C>T p.D335= | Silent (SNP) | VAF 55/576 reads (10%) | catalogued as COSV99059349; called by muse, mutect2
- C1QL3 | c.708C>A p.A236= | Silent (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2
- C20orf144 | c.249G>A p.A83= | Silent (SNP) | VAF 46/406 reads (11%) | catalogued as rs776103523; called by muse, mutect2, varscan2
- CASKIN1 | c.3339G>A p.P1113= | Silent (SNP) | VAF 28/197 reads (14%) | catalogued as rs752950329; called by muse, mutect2, varscan2
- CPS1 | c.4056C>T p.S1352= | Silent (SNP) | VAF 44/409 reads (11%) | called by muse, varscan2
- CRHR2 | c.1170C>A p.A390= | Silent (SNP) | VAF 36/248 reads (15%) | called by muse, mutect2, varscan2
- DMRTB1 | c.537G>A p.R179= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- DNAH1 | c.10515G>T p.L3505= | Silent (SNP) | VAF 66/364 reads (18%) | called by muse, mutect2, varscan2
- DNAH7 | c.9186A>T p.T3062= | Silent (SNP) | VAF 26/229 reads (11%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.1065T>C p.L355= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- EIF4H | c.261A>G p.V87= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- EPHA3 | c.1161T>C p.F387= | Silent (SNP) | VAF 40/526 reads (8%) | catalogued as COSV60734343; called by muse, mutect2
- EYA1 | c.1704G>C p.A568= | Silent (SNP) | VAF 68/609 reads (11%) | catalogued as COSV58173641; called by muse, mutect2, varscan2
- EYS | c.1485G>T p.G495= | Silent (SNP) | VAF 40/327 reads (12%) | called by muse, mutect2, varscan2
- FGF12 | c.123C>T p.C41= | Silent (SNP) | VAF 20/284 reads (7%) | catalogued as rs753826180; called by muse, mutect2
- GAS2L3 | c.1854A>T p.L618= | Silent (SNP) | VAF 47/300 reads (16%) | called by muse, mutect2, varscan2
- GRIP1 | c.414G>T p.P138= | Silent (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- HECW2 | c.477G>T p.V159= | Silent (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- HIC2 | c.1452C>T p.A484= | Silent (SNP) | VAF 20/301 reads (7%) | catalogued as rs759072083, COSV68041883; called by muse, mutect2
- IMPA2 | c.699G>A p.A233= | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as rs750911716; called by muse, mutect2
- ITGA8 | c.3135T>A p.P1045= | Silent (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- KCNH6 | c.1821C>T p.A607= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs1412413624; called by muse, mutect2, varscan2
- KLHDC7B | c.408C>T p.C136= (on ENST00000395676; = p.C777= on NM_138433.5) | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs1392449882, COSV67464424; called by muse, mutect2
- KLHL4 | c.2127T>C p.G709= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- LAMA2 | c.8022C>G p.L2674= | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as COSV70353318; called by muse, mutect2, varscan2
- LIMCH1 | c.780G>A p.P260= | Silent (SNP) | VAF 31/673 reads (5%) | catalogued as rs1199516744, COSV58272789; called by muse, mutect2
- LPAR4 | c.903T>C p.T301= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1260862307; called by muse, mutect2, varscan2
- LYRM1 | c.300T>C p.L100= | Silent (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- MUC16 | c.11538A>T p.P3846= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV101201749; called by muse, varscan2
- MUC3A | c.9228C>A p.S3076= | Silent (SNP) | VAF 46/766 reads (6%) | catalogued as COSV60223013; called by muse, mutect2
- MYO1A | c.1722C>T p.L574= | Silent (SNP) | VAF 38/600 reads (6%) | catalogued as rs1309143468; called by muse, mutect2
- OR4K15 | c.798T>C p.A266= (on ENST00000305051; = p.A242= on NM_001005486.1) | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as rs773995793; called by muse, mutect2, varscan2
- OR51B2 | c.645C>T p.S215= | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- OR5AP2 | c.663C>G p.L221= | Silent (SNP) | VAF 27/260 reads (10%) | called by muse, mutect2, varscan2
- OR5J2 | c.99G>A p.V33= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as COSV56620132; called by muse, mutect2, varscan2
- PCDH17 | c.2805A>G p.E935= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs1290086208; called by muse, mutect2, varscan2
- PHF10 | c.870T>C p.P290= | Silent (SNP) | VAF 37/282 reads (13%) | called by muse, mutect2, varscan2
- PIK3R1 | c.249G>A p.S83= | Silent (SNP) | VAF 25/247 reads (10%) | catalogued as rs771574512, COSV99140525; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXNA1 | c.3687G>A p.S1229= | Silent (SNP) | VAF 21/187 reads (11%) | catalogued as rs556545622, COSV99302176; called by muse, mutect2, varscan2
- PODXL2 | c.711C>T p.S237= | Silent (SNP) | VAF 115/470 reads (24%) | called by muse, mutect2, varscan2
- PTPN4 | c.1032T>C p.Y344= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- PTPN6 | c.483G>T p.P161= | Silent (SNP) | VAF 87/627 reads (14%) | called by muse, mutect2, varscan2
- RAD50 | c.2265G>A p.Q755= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- RGS11 | c.843C>T p.Y281= (on ENST00000397770 / NM_183337.3; = p.Y260= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/235 reads (15%) | called by muse, mutect2, varscan2
- SCN4A | c.540C>A p.G180= | Silent (SNP) | VAF 44/359 reads (12%) | called by muse, mutect2, varscan2
- SLC22A10 | c.1263G>A p.L421= | Silent (SNP) | VAF 43/338 reads (13%) | called by muse, mutect2, varscan2
- SLC25A32 | c.327T>C p.Y109= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2, varscan2
- SOHLH1 | c.508C>T p.L170= | Silent (SNP) | VAF 91/602 reads (15%) | catalogued as rs986540910; called by muse, mutect2, varscan2
- TAF1L | c.2766T>C p.Y922= | Silent (SNP) | VAF 53/409 reads (13%) | called by muse, mutect2, varscan2
- TENT4A | c.1659C>T p.G553= | Silent (SNP) | VAF 21/216 reads (10%) | catalogued as rs1401911338; called by muse, mutect2
- TEX49 | c.306C>A p.I102= | Silent (SNP) | VAF 25/262 reads (10%) | called by muse, mutect2
- TEX49 | c.307C>A p.R103= | Silent (SNP) | VAF 24/253 reads (9%) | called by muse, mutect2
- TLE1 | c.1899G>C p.T633= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV64719291, COSV64719443; called by muse, mutect2, varscan2
- TMEM132D | c.648G>T p.V216= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as COSV101399903; called by muse, mutect2, varscan2
- TMEM51 | c.282C>T p.G94= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as rs1185801385, COSV65690876; called by muse, mutect2
- TNFAIP6 | c.117C>T p.H39= | Silent (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- TRIM42 | c.1263C>T p.N421= | Silent (SNP) | VAF 64/352 reads (18%) | catalogued as rs763116617; called by muse, mutect2, varscan2
- TRMT12 | c.930G>T p.L310= | Silent (SNP) | VAF 45/331 reads (14%) | called by muse, mutect2, varscan2
- TSHZ2 | c.1758A>T p.P586= | Silent (SNP) | VAF 33/299 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.101574A>T p.G33858= (on ENST00000591111; = p.G26434= on NM_003319.4) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1307029109; called by muse, mutect2, varscan2
- VPS13B | c.3012C>T p.P1004= | Silent (SNP) | VAF 76/550 reads (14%) | catalogued as rs199519352; called by muse, varscan2
- VSTM2A | c.564C>A p.A188= | Silent (SNP) | VAF 43/253 reads (17%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2682G>T p.V894= | Silent (SNP) | VAF 104/705 reads (15%) | called by muse, mutect2, varscan2
- ZNF697 | c.1185C>T p.D395= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs1376224595; called by muse, varscan2
- ADGB | c.4818+5500C>A | Intron (SNP) | VAF 16/307 reads (5%) | called by muse, mutect2
- AFF3 | chr2:100105509 A>G | 5'Flank (SNP) | VAF 48/280 reads (17%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850973 G>T | 3'Flank (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- AP5Z1 | c.-47G>T | 5'UTR (SNP) | VAF 21/178 reads (12%) | catalogued as rs758255753; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+113G>C | Intron (SNP) | VAF 56/535 reads (10%) | called by muse, mutect2
- CHRNA4 | c.*2883C>A | 3'UTR (SNP) | VAF 38/554 reads (7%) | called by muse, mutect2
- CNGA3 | c.216-35dup | Intron (INS) | VAF 44/386 reads (11%) | called by pindel, varscan2
- COCH | c.35-41G>A | Intron (SNP) | VAF 92/652 reads (14%) | called by muse, mutect2, varscan2
- DDR2 | c.1504+12G>C | Intron (SNP) | VAF 19/269 reads (7%) | called by muse, mutect2
- DLG2 | c.205-65622G>T | Intron (SNP) | VAF 22/319 reads (7%) | catalogued as COSV54625010; called by muse, mutect2
- EIF3IP1 | n.159A>T | RNA (SNP) | VAF 32/229 reads (14%) | called by muse, mutect2, varscan2
- ERGIC3 | chr20:35560230 C>T | 3'Flank (SNP) | VAF 30/414 reads (7%) | catalogued as rs572134744; called by muse, mutect2
- FAM197Y1 | n.608C>A | RNA (SNP) | VAF 95/325 reads (29%) | called by muse, mutect2, varscan2
- FGFR1 | c.936+38G>T | Intron (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- GATA3 | c.*25C>A | 3'UTR (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.301G>T | RNA (SNP) | VAF 52/797 reads (7%) | called by muse, mutect2
- KCTD7 | c.-83C>T | 5'UTR (SNP) | VAF 24/150 reads (16%) | catalogued as rs958093696; called by muse, mutect2, varscan2
- LAMA3 | c.4998+1526C>T | Intron (SNP) | VAF 99/848 reads (12%) | catalogued as rs780094876; called by muse, mutect2, varscan2
- LAMB1 | c.38-33T>A | Intron (SNP) | VAF 18/151 reads (12%) | called by muse, varscan2
- LOXL3 | c.*614G>A | 3'UTR (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- LOXL3 | c.*613T>G | 3'UTR (SNP) | VAF 42/311 reads (14%) | catalogued as rs1305235888; called by muse, mutect2, varscan2
- MASP1 | c.-39G>T | 5'UTR (SNP) | VAF 139/1114 reads (12%) | called by muse, mutect2, varscan2
- MIR412 | n.88G>T | RNA (SNP) | VAF 22/404 reads (5%) | called by muse, mutect2
- MRPL43 | c.466-239G>A | Intron (SNP) | VAF 16/187 reads (9%) | catalogued as rs141726768; called by muse, mutect2
- MYC | c.-24G>C | 5'UTR (SNP) | VAF 33/307 reads (11%) | catalogued as COSV104388229, COSV52373180; called by muse, mutect2, varscan2
- NACA | c.70+3218C>T | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as rs756742476; called by muse, mutect2, varscan2
- NAMPTP1 | n.1173del | RNA (DEL) | VAF 58/437 reads (13%) | called by mutect2, pindel, varscan2
- OFCC1 | n.1707T>C | RNA (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
- PIGK | c.987-6994T>A | Intron (SNP) | VAF 30/633 reads (5%) | called by muse, mutect2
- SIGLEC10 | c.-5C>T | 5'UTR (SNP) | VAF 19/177 reads (11%) | catalogued as rs373934395; called by muse, mutect2, varscan2
- SIGLEC10 | c.-6G>T | 5'UTR (SNP) | VAF 19/176 reads (11%) | called by muse, mutect2, varscan2
- SLC4A1 | c.*10C>A | 3'UTR (SNP) | VAF 36/436 reads (8%) | called by muse, mutect2
- SRL | c.62-2833C>T | Intron (SNP) | VAF 14/321 reads (4%) | called by muse, mutect2
- STEAP1B | c.706-18796C>T | Intron (SNP) | VAF 34/442 reads (8%) | catalogued as rs1177505813, COSV68347467; called by muse, mutect2
- STIM2 | c.1764-955G>A | Intron (SNP) | VAF 34/312 reads (11%) | called by muse, mutect2, varscan2
- THY1 | c.*36G>T | 3'UTR (SNP) | VAF 15/289 reads (5%) | called by muse, mutect2
- TLCD2 | chr17:1712365 C>A | 5'Flank (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- TNS2 | c.350+15T>A | Intron (SNP) | VAF 49/344 reads (14%) | catalogued as rs754217469; called by muse, mutect2, varscan2
- TSPY8 | c.-2G>A | 5'UTR (SNP) | VAF 31/266 reads (12%) | catalogued as COSV99819090, COSV99819093; called by muse, mutect2, varscan2
- USP25 | c.2337+5217dup | Intron (INS) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- YIF1B | c.789+454G>A | Intron (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- ZNF252P | n.2126G>A | RNA (SNP) | VAF 31/242 reads (13%) | called by muse, mutect2, varscan2
